Somatic mutation profile of tumor specimen BA2955D (aliquot aq-BA2955D) from BEATAML1.0 case 2039, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,281 days).
Specimen BA2955D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 989e021b-97c6-4688-92b3-1d301fee19d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2773D (Solid Tissue Normal), aliquot aq-BA2773D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/524e84ac-2be3-4f8a-a227-5a989ad5b4fa

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4976G>A p.G1659E (on ENST00000378444 / NM_001123385.2; = p.G1625E on NM_017745.6) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100654240; called by muse, mutect2
- GRM2 | c.1864A>G p.I622V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, varscan2
- GTF3C4 | c.1601T>C p.F534S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ITGB4 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2
- RALGDS | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TFAP4 | c.513G>T p.M171I | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- TMEM19 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADRM1 | c.918C>A p.V306= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99440229; called by muse, mutect2, varscan2
- TMCO1 | c.*2115T>G | 3'UTR (SNP) | VAF 37/123 reads (30%) | called by muse, mutect2, varscan2
